FM case AD14634 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/be822bf7-1c3c-4a51-8df1-ae41d102b1ce

Male, 77.7 years: diagnosis not reported by GDC; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
